Somatic mutation profile of tumor specimen TARGET-10-PASKSY-09A (aliquot TARGET-10-PASKSY-09A-01D) from TARGET case TARGET-10-PASKSY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,552 days).
Specimen TARGET-10-PASKSY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 476fe7d9-f542-4071-a0e0-2705829a8b2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASKSY-10A (Blood Derived Normal), aliquot TARGET-10-PASKSY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ace01291-75aa-4423-bad2-b89c8306efdb

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Frame Shift Ins 8, Intron 4, Nonsense Mutation 4, Silent 3, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRE2 | c.94T>C p.W32R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59692994; called by muse, mutect2, varscan2
- ANK2 | c.3007C>T p.R1003* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as COSV52156986; called by muse, mutect2, varscan2
- AXDND1 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 53/132 reads (40%) | catalogued as rs146917473, COSV100858295; called by muse, mutect2, varscan2
- C12orf56 | c.1450C>A p.L484M (on ENST00000543942 / NM_001170633.2; = p.L324M on NM_001099676.3) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.576); catalogued as COSV61486589; called by muse, mutect2, varscan2
- DOCK3 | c.5000G>A p.R1667Q | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370848128; called by muse, mutect2, varscan2
- EZH2 | c.1955A>G p.D652G (on ENST00000460911 / NM_001203247.2; = p.D657G on NM_004456.5) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57451342; called by muse, mutect2, varscan2
- GPR32 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.86); catalogued as rs762467590, COSV54514274; called by muse, mutect2, varscan2
- MAP3K21 | c.2824G>A p.V942M | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs750380229, COSV64041506; called by muse, mutect2, varscan2
- MAT1A | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64745345; called by muse, mutect2, varscan2
- MYB | c.41_42insAAAGGGCTTAGGCGCTTCCCA p.E14_D15insKGLGASQ | In Frame Ins (INS) | VAF 11/35 reads (31%) | catalogued as COSV57198855, COSV57201532, COSV57203337; called by mutect2, pindel
- NMUR2 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779692169, COSV54918661; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>A p.L1600Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- OR52W1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60950843; called by muse, mutect2, varscan2
- RIN2 | c.1049C>T p.T350M (on ENST00000255006 / NM_001242581.1; = p.T301M on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV54787088; called by muse, mutect2, varscan2
- SERPINA4 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 43/88 reads (49%) | catalogued as rs767258699, COSV54069068, COSV54069161; called by muse, mutect2, varscan2
- SVIL | c.4386_4387insAAGACGAC p.A1463Kfs*25 (on ENST00000355867 / NM_021738.3; = p.A1037Kfs*25 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | catalogued as COSV63442572; called by mutect2, pindel, varscan2
- TNRC6B | c.1771delinsGGA p.R591Gfs*19 | Frame Shift Ins (INS) | VAF 20/57 reads (35%) | catalogued as COSV57299596; called by pindel, varscan2*
- TOM1L1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs1228352535; called by muse, mutect2
- TRBV20-1 | c.185C>A p.A62E | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755581253; called by muse, mutect2, varscan2
- ZNF865 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV57595899; called by muse, mutect2, varscan2
- AEBP2 | c.1218_1219insGAGGGGA p.R407Efs*10 | Frame Shift Ins (INS) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.2309_2310insTTGGG p.E771Wfs*9 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- DNM2 | c.2251_2257dup p.D753Afs*4 (on ENST00000355667 / NM_001005360.3; = p.D749Afs*4 on NM_004945.3) | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, varscan2
- MED12 | c.2069_2078dup p.E694Yfs*4 | Frame Shift Ins (INS) | VAF 62/80 reads (78%) | called by mutect2, varscan2
- NOTCH1 | c.7020dup p.S2341Lfs*13 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | called by mutect2, pindel, varscan2
- RREB1 | c.179_180insCTCCCCCACCAGA p.K60Nfs*12 | Frame Shift Ins (INS) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- FLNB | c.5580C>T p.G1860= | Silent (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.51C>T p.D17= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs766389811, COSV51533505; called by muse, mutect2, varscan2
- NPRL2 | c.126G>A p.V42= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs966831292; called by muse, mutect2, varscan2
- AC011525.1 | n.597C>T | RNA (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- FARP2 | c.1812-26G>T | Intron (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- PDCD2 | c.763-62T>C | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-668G>A | Intron (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- SCNN1D | c.-121-80G>A | Intron (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
